Surgical pathology report (de-identified scan), TCGA case TCGA-27-2521, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Milan - Italy, Fondazione IRCCS Instituto Neuroligico C. Besta, specimen TCGA-27-2521-01A (Primary Tumor).

TCGA-27-2521

Ref. Number

Gender

Birth date

Tumor site

Right fronto-temporal

Histological diagnosis

Glioblastoma multiforme

Source: NCI Genomic Data Commons file 8ee87141-92c6-49f7-9ac3-9381b74f9380 (TCGA-27-2521.3B0EADC8-F7C7-4458-A24F-5391314B8490.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).